Gene-level copy-number profile of tumor specimen TCGA-DC-6158-01A from TCGA case TCGA-DC-6158, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 70.8 years (25,842 days).
Specimen TCGA-DC-6158-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.3a507f7e-84c1-4aae-b01e-93414956247e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-6158-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 823 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/783679c4-f186-4d6c-8767-99300eae76fa

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 2,087; copy number 2: 21,629; copy number 3: 25,403; copy number 4: 7,141; copy number 5: 228; copy number 6: 2,174; copy number 7: 1,083; copy number 8: 21; copy number 10: 15; copy number 13: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-6158-01A-11D-1656-01): tumor purity 0.54, ploidy 2.81, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:108,008,898–108,121,684, 3 genes (within-gene range 0–2): CUL5, Y_RNA, AP002433.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,135 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:2,907,073–3,691,814, 6 genes, copy number 8 (within-gene range 2–8): CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2.
- chr9:4,944,670–5,185,647, 15 genes, copy number 8 (within-gene range 2–8): HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6.
- chr11:60,850,933–61,161,615, 15 genes, copy number 10 (within-gene range 2–10): PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1.
- chr11:64,449,074–65,883,741, 108 genes, copy number 7 (broad region; genes not listed).
- chr11:67,056,847–68,053,762, 69 genes, copy number 7 (broad region; genes not listed).
- chr11:69,909,184–69,926,813, 2 genes, copy number 13: AP007216.1, AP007216.2.
- chr11:70,270,690–70,385,312, 1 gene, copy number 13 (within-gene range 2–13): PPFIA1.
- chr11:70,282,367–70,363,368, 1 gene, copy number 13 (within-gene range 2–13): AP002336.2.
- chr11:70,319,928–70,436,584, 5 genes, copy number 13: AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:74,012,718–74,311,640, 7 genes, copy number 13 (within-gene range 2–13): C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1.
- chr11:75,717,838–75,815,406, 7 genes, copy number 7: MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr20:30,214,765–64,313,132, 899 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,087. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
